MMRF case MMRF_2596 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/d00e73a5-08e5-42cf-9634-512e084d8d87

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 73 years; Vital status: Dead; Days to death: 139 days; Cause of death: Not Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 73.2 years (26,728 days); ISS stage: I; Days to last known disease status: 139 days; Days to last follow up: 139 days.
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 32 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 11 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 78 days; Days to treatment end: 78 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 79 days; Days to treatment end: 79 days.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 139.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -19 (ECOG 0): M Protein 0.33 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 69.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.59 mg/dL; Immunoglobulin G 6.24 g/L; Immunoglobulin A 0.28 g/L; Immunoglobulin M 0.19 g/L; Beta 2 Microglobulin 1.88 µg/mL; Lactate Dehydrogenase 4.07 µkat/L; Hemoglobin 7.07 mmol/L; Leukocytes 6.3 ×10⁹/L; Absolute Neutrophil 3.8 ×10⁹/L; Platelets 191 ×10⁹/L; Creatinine 80.4 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.4 mmol/L; Albumin 46 g/L; Total Protein 6.8 g/dL; Glucose 6.49 mmol/L.
- Day 84 (ECOG 1): M Protein 0.15 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.57 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.149 mg/dL; Immunoglobulin G 3.75 g/L; Immunoglobulin A 0.39 g/L; Immunoglobulin M 0.49 g/L; Beta 2 Microglobulin 2.18 µg/mL; Lactate Dehydrogenase 14.4 µkat/L; Hemoglobin 5.33 mmol/L; Leukocytes 6 ×10⁹/L; Absolute Neutrophil 5.9 ×10⁹/L; Platelets 126 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.15 mmol/L; Albumin 34 g/L; Total Protein 5.5 g/dL; Glucose 11.1 mmol/L.
- Day 138 (ECOG 3): M Protein 0.19 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.288 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.75 mg/dL; Immunoglobulin G 5.58 g/L; Immunoglobulin A 1.29 g/L; Immunoglobulin M 0.51 g/L; Lactate Dehydrogenase 4.1 µkat/L; Hemoglobin 5.08 mmol/L; Leukocytes 7 ×10⁹/L; Absolute Neutrophil 5.1 ×10⁹/L; Platelets 217 ×10⁹/L; Creatinine 67.2 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.03 mmol/L; Albumin 32 g/L; Total Protein 5.9 g/dL; Glucose 6.05 mmol/L.

Other clinical attributes
- Day -19: Weight: 92 kg; Height: 152 cm.

Biospecimens (2 samples)
- Sample MMRF_2596_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -19 days.
- Sample MMRF_2596_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -19 days.
